Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A3JI, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A3JI-06A (Metastatic).

[page 1 of 2]
1 CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary C77.3

12/13/11 lw

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

M58. History of multiple previous melanomas (patient recounts 8, and there are 5 histologically-confirmed ones on the files).

- (L) infraclavicular - depth 1.2mm, level IV, mit 1/mm2.
- (R) hypochondrium - depth 1.1mm, level III, mit 0/mm2.
- (R) thigh medially - dysplastic naevus with focal in-situ melanoma
- (L) forearm - depth 1.6mm, level IV, mit 2/mm2, spindled, treated with WE and (L) axillary SNB x1 (0/1).
- (L) loin - borderline lesion (?traumatized naevus), depth 1.2mm, treated with WE and (L) groin SNBs (clear).
- upper abd - depth 0.35mm.

* Presented in with a large palpable node low in the (L) axilla. FNA) showed metastatic melanoma. Staging CT was clear.

Operation: (L) axillary clearance.

Specimen: (L) axillary lymph node dissection.

MACROSCOPIC DESCRIPTION

"LEFT AXILLARY CONTENTS + TUMOUR BANK". A mass of fibrofatty tissue 195 x 100 x 40mm, with attached muscle 110 x 30 x 50mm.

A solitary well-circumscribed tumorous node is present, 60 x 45 x 40mm, its cut surface fairly uniformly tan fleshy. It is clear of the surgical margins.

A 10 x 10 x 10mm piece of fresh tissue taken for tumour banking

Macro photos x3 taken

Blocks:

- A. ?Four nodes.
- B. ?Four nodes.
- C. ?Four nodes.
- D. ?Four nodes.
- E. ?Four nodes.
- F. ?Four nodes.
- G. ?Four nodes.

H-K. Section of the largest tumour.

MICROSCOPIC REPORT

The (L) axillary dissection shows metastatic malignant melanoma, involving 1 (one) of 23 nodes.

Growth pattern: The large involved node is virtually replaced (>99%) by solid tumour, which expands the node capsule.

Focally in block 1H, the capsule is invaded and breached over a 1.5mm dia area with tumour cells going just into fat (slides 1H1-3) - (microscopic extranodal extension).

Most of the tumour is viable, though some early necrosis is seen in places.

Tumour histology: The melanoma has an epithelioid cytomorphology, with large nucleoli and mild nuclear pleomorphism.

[page 2 of 2]
Requested by:

HISTOPATHOLOGY REPORT

Mitotic rate is high at 14/mm², and Ki67 labelling is about 20%.
There is a small amount of cytoplasmic pigment.

Other comments: No definite TILs response or regression.

SUMMARY

(L) axillary lymph node dissection - **Metastatic MELANOMA (1/23 nodes).**
60mm dia, focal extranodal extension.
Mitoses 14/mm².

REPORTED BY: I

Printed:

Page 2 of 2

Source: NCI Genomic Data Commons file 2a427fb6-568c-4cec-9178-7b78d8c6443d (TCGA-EE-A3JI.A1A21256-D045-4A0C-8B65-CB9F46BBF920.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).